Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A1NK, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A1NK-01A (Primary Tumor).

Pathology Reports

Requisition ☐ run at

Case ID	OpenClinica Subject ID	Formatted Path Report	Laterality	Date of Procurement
		SKIN TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Skin Tumor size: 1.5 x 1 x 1 cm Tumor features: Ulcerated, Pigmented Satellite nodules: Not specified Histologic type: Malignant melanoma Histologic grade: Moderately differentiated Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: 4th Level by	NA	

1CD-0-3
Melanoma, NOS 8720/3
Site: Skin, NOS 644.9 per 3/1/11

LUID: F97E7885-4128-46AC-8BF3-BAE05A4413D0

Diagnostic Discrepancy		
RPAA Discrepancy		
Case E (Article)		

KMI per 3/1/11

Source: NCI Genomic Data Commons file b4da0f6f-a229-45e3-8f76-edb1a044bd03 (TCGA-EB-A1NK.F97E7885-4128-46AC-8BF3-BAE05A4413D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).